Somatic mutation profile of tumor specimen MP2PRT-PAVHGW-TMP1-A (aliquot MP2PRT-PAVHGW-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVHGW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.0 years (6,202 days).
Specimen MP2PRT-PAVHGW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f2e603e-d2dc-45b4-8706-c05a318c9f5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVHGW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVHGW-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20aa94fb-199b-4792-9a77-e50f0286adda

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Silent 5, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP3 | c.2042G>A p.C681Y | Missense Mutation (SNP) | VAF 72/369 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777564745; called by muse, mutect2
- COL22A1 | c.3625G>T p.A1209S | Missense Mutation (SNP) | VAF 79/424 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.029); catalogued as rs1159851210; called by muse, mutect2, varscan2
- IGKV2-30 | chr2:89244780 del GA | Missense Mutation (DEL) | VAF 34/146 reads (23%) | catalogued as rs1363281995; called by pindel, varscan2
- PGRMC2 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 221/843 reads (26%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.06); catalogued as rs1026654012; called by muse, mutect2, varscan2
- PRR3 | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 65/445 reads (15%) | catalogued as rs371871050; called by muse, mutect2, varscan2
- RTL4 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 191/417 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs771574786, COSV61206598; called by muse, mutect2, varscan2
- ZAN | c.6199G>A p.G2067S | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs541847729; called by muse, mutect2
- CEP126 | c.891T>A p.D297E | Missense Mutation (SNP) | VAF 147/655 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.315); called by muse, mutect2
- DDB1 | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 224/452 reads (50%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- DIXDC1 | c.1496G>T p.G499V (on ENST00000440460 / NM_001037954.4; = p.G288V on NM_033425.4) | Missense Mutation (SNP) | VAF 60/360 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- EML2 | c.433G>T p.V145F | Missense Mutation (SNP) | VAF 66/324 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- GABRG3 | c.1277C>A p.S426* | Nonsense Mutation (SNP) | VAF 68/253 reads (27%) | called by muse, mutect2, varscan2
- KIAA2012 | c.890C>A p.T297K | Missense Mutation (SNP) | VAF 133/519 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- NTRK2 | c.1210G>C p.A404P | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- XBP1 | c.493delinsTC p.A165Sfs*222 | Frame Shift Ins (INS) | VAF 104/588 reads (18%) | called by mutect2*, pindel, varscan2*
- ANKRD30B | c.1704G>A p.K568= | Silent (SNP) | VAF 56/175 reads (32%) | called by muse, mutect2, varscan2
- HTR2A | c.651C>T p.D217= | Silent (SNP) | VAF 67/328 reads (20%) | catalogued as rs533066466, COSV66326736; called by muse, mutect2, varscan2
- PCDHB15 | c.741C>T p.Y247= | Silent (SNP) | VAF 90/244 reads (37%) | called by muse, mutect2, varscan2
- RGS7 | c.1023A>C p.P341= | Silent (SNP) | VAF 127/537 reads (24%) | called by muse, mutect2, varscan2
- SIGIRR | c.393C>T p.A131= | Silent (SNP) | VAF 143/713 reads (20%) | catalogued as rs1240565120, COSV58989502; called by muse, mutect2, varscan2
